Somatic mutation profile of tumor specimen TARGET-20-PASXIS-09A (aliquot TARGET-20-PASXIS-09A-01D) from TARGET case TARGET-20-PASXIS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,318 days).
Specimen TARGET-20-PASXIS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14a66f54-73a6-4858-8df6-414f759f8f15.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXIS-14A (Bone Marrow Normal), aliquot TARGET-20-PASXIS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c30ff19e-822c-4596-9da6-2ea1d8aedf61

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62002969, COSV62003176; called by muse, mutect2, varscan2
- IKZF1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58780577; called by muse, mutect2
- PCLO | c.1161G>T p.G387= | Silent (SNP) | VAF 115/311 reads (37%) | called by muse, mutect2, varscan2
